Somatic mutation profile of tumor specimen TCGA-2Y-A9HA-01A (aliquot TCGA-2Y-A9HA-01A-11D-A38X-10) from TCGA case TCGA-2Y-A9HA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 70.9 years (25,892 days).
Specimen TCGA-2Y-A9HA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 716b210f-5463-4c3b-804e-c92ba696d3ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Y-A9HA-10A (Blood Derived Normal), aliquot TCGA-2Y-A9HA-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13f8f2f3-bfa9-404d-8ef4-0ca6c0661f77

The open-access MAF lists 156 somatic variants for this specimen: 121 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 32, Nonsense Mutation 7, Splice Site 5, Frame Shift Del 4, In Frame Del 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 55/136 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM12 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751757189, COSV100899911; called by muse, mutect2, varscan2
- ADGRL3 | c.3677C>A p.S1226Y (on ENST00000506720 / NM_001322402.2; = p.S1158Y on NM_015236.6) | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101546797, COSV72230116; called by muse, mutect2
- AHSG | c.296G>T p.R99I | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV99889769; called by muse, mutect2, varscan2
- AK9 | c.3104A>T p.E1035V | Missense Mutation (SNP) | VAF 116/246 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100392956; called by muse, mutect2, varscan2
- ANKS3 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs747928992, COSV100172714; called by muse, mutect2, varscan2
- ANO3 | c.1107G>T p.W369C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56811269, COSV99879961; called by muse, mutect2, varscan2
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- ARHGAP18 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.24); PolyPhen benign (0.231); catalogued as COSV100935992; called by muse, mutect2, varscan2
- ARX | c.1681G>T p.V561L | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV100984028; called by muse, mutect2, varscan2
- CCDC68 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1359135096, COSV100491556; called by muse, mutect2, varscan2
- CD47 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs867558279, COSV62528376; called by muse, mutect2, varscan2
- CDH15 | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.752); catalogued as COSV99227891; called by muse, mutect2, varscan2
- CEP95 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99857539; called by muse, mutect2, varscan2
- CLPB | c.865+2T>C p.X289_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99577504; called by muse, mutect2, varscan2
- CLSTN2 | c.564C>A p.C188* | Nonsense Mutation (SNP) | VAF 51/129 reads (40%) | catalogued as COSV101515424; called by muse, mutect2, varscan2
- COL11A1 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100614609; called by muse, mutect2, varscan2
- DCC | c.1796T>A p.L599* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100497577, COSV59101638; called by muse, mutect2, varscan2
- DEFB113 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100435340; called by muse, mutect2, varscan2
- DENND2B | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs764376826, COSV58205748; called by muse, mutect2, varscan2
- DIP2C | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as rs1457743486, COSV99789683; called by muse, mutect2, varscan2
- DLG2 | c.283C>T p.Q95* (on ENST00000650630 / NM_001351274.2; = p.Q58* on NM_001142699.3) | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV101070079; called by muse, mutect2, varscan2
- DNAH7 | c.8818A>G p.R2940G | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1370270155, COSV100413505; called by muse, mutect2, varscan2
- DNAI4 | c.171-1G>A p.X57_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100925197, COSV100925236; called by muse, mutect2, varscan2
- DNMT3A | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1036696061, COSV53043979, COSV53051837, COSV53086390; called by muse, mutect2, varscan2
- DNMT3A | c.575C>A p.A192E | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53037374, COSV99258021; called by muse, mutect2, varscan2
- DSCAM | c.5902G>A p.V1968M | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs746017443, COSV68035652; called by muse, mutect2, varscan2
- EFEMP1 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 134/381 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.296); catalogued as COSV100816694; called by muse, varscan2
- EVC2 | c.1866C>G p.H622Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100184808; called by muse, mutect2, varscan2
- EZH1 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99226048; called by muse, mutect2, varscan2
- FAM117B | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as COSV100286988, COSV57418864; called by muse, mutect2, varscan2
- FBH1 | c.225G>T p.M75I (on ENST00000362091 / NM_178150.3; = p.M126I on NM_032807.4) | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.115); catalogued as COSV62982643; called by muse, mutect2, varscan2
- FER1L6 | c.3968G>T p.G1323V | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV101205295; called by muse, mutect2
- FLVCR1 | c.1594-2A>G p.X532_splice | Splice Site (SNP) | VAF 75/272 reads (28%) | catalogued as COSV100874984; called by muse, mutect2
- GABPB1 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV99589499; called by muse, mutect2, varscan2
- GABRA1 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT tolerated (0.82); PolyPhen benign (0.03); catalogued as rs1424508480, COSV99195677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA1 | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 103/219 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as COSV50099171, COSV99195678; called by muse, mutect2, varscan2
- GPRC6A | c.2107A>G p.R703G | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1338337169, COSV100113943; called by muse, mutect2, varscan2
- GRID2 | c.1010C>A p.A337D | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV99936234; called by muse, mutect2, varscan2
- HAGHL | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as rs776435642, COSV99284490; called by muse, mutect2, varscan2
- HAVCR1 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs181065847, COSV100207838; called by muse, mutect2, varscan2
- HBP1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.086); catalogued as COSV99752927; called by muse, mutect2
- HMCN1 | c.8681G>A p.C2894Y | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750532975, COSV99622949; called by muse, mutect2, varscan2
- HOXB1 | c.546G>C p.W182C | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53318543, COSV99495266; called by muse, mutect2, varscan2
- HSP90AB1 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1252188086, COSV100806892; called by muse, mutect2
- HSPA12B | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99421895; called by muse, mutect2, varscan2
- IGFALS | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV51905097, COSV99236303; called by muse, mutect2, varscan2
- IMPA1 | c.541A>C p.K181Q | Missense Mutation (SNP) | VAF 89/484 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99808738; called by muse, mutect2, varscan2
- ITGA11 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485925620, COSV100240756; called by muse, mutect2, varscan2
- KCNA6 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99768244; called by muse, mutect2, varscan2
- KCNH7 | c.1690C>A p.H564N | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100033633; called by muse, mutect2, varscan2
- KPNA5 | c.1300A>T p.T434S | Missense Mutation (SNP) | VAF 97/178 reads (54%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); catalogued as COSV100706043; called by muse, mutect2, varscan2
- LAMA5 | c.7879A>C p.K2627Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99437510; called by muse, mutect2, varscan2
- LPIN2 | c.2675T>A p.L892Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as COSV99598044; called by muse, mutect2, varscan2
- MAD1L1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs778331393, COSV56234355, COSV99764934; called by muse, mutect2, varscan2
- MAGI3 | c.3567A>C p.K1189N | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV100287840; called by muse, mutect2, varscan2
- MARCHF8 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100165489; called by muse, mutect2, varscan2
- MATN4 | c.1609G>T p.A537S (on ENST00000372754; = p.A496S on NM_003833.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | PolyPhen probably damaging (1); catalogued as COSV100636837; called by muse, mutect2, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 107/308 reads (35%) | catalogued as rs747811015; called by mutect2, pindel, varscan2
- MUC4 | c.16195G>A p.A5399T (on ENST00000463781 / NM_018406.7; = p.A1163T on NM_004532.6) | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772843001, COSV100203228; called by muse, mutect2, varscan2
- NFAT5 | c.1815A>C p.E605D | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100590344; called by muse, mutect2, varscan2
- NMUR2 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as COSV99676524; called by muse, mutect2, varscan2
- NOTCH4 | c.4423C>T p.R1475C | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV100900296; called by muse, mutect2, varscan2
- NPR2 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.023); catalogued as COSV100709237; called by muse, mutect2, varscan2
- NR0B1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as rs780289680, COSV100973421; called by muse, mutect2
- NRDC | c.647T>G p.F216C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100702975; called by muse, mutect2, varscan2
- NUP133 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 24/45 reads (53%) | catalogued as COSV99772467; called by muse, mutect2, varscan2
- NUTM1 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100412009; called by muse, mutect2, varscan2
- OBSL1 | c.2915T>C p.I972T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as rs535601955, COSV99216014; called by muse, mutect2, varscan2
- OLFML2B | c.1977G>T p.Q659H | Missense Mutation (SNP) | VAF 226/524 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV54200353, COSV99667943; called by muse, varscan2
- OR8D2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs201080079, COSV100658863; called by muse, mutect2, varscan2
- OR8U1 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV56413879; called by muse, mutect2, varscan2
- PCLO | c.2672C>A p.T891K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV100426523, COSV100439560; called by muse, mutect2, varscan2
- PGR | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867516411, COSV99677268; called by muse, mutect2
- PHC1 | c.1297C>A p.Q433K | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.678); catalogued as COSV101418489; called by muse, mutect2, varscan2
- PHLDB1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs782543582, COSV100616195; called by muse, mutect2, varscan2
- PLA2G4C | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV100843808; called by muse, mutect2
- PRKDC | c.1803G>T p.W601C | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.598); catalogued as COSV100038031; called by muse, mutect2, varscan2
- PTPRT | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as COSV100624493; called by muse, mutect2, varscan2
- RAB3C | c.25-1G>A p.X9_splice | Splice Site (SNP) | VAF 93/211 reads (44%) | catalogued as COSV99276539; called by muse, mutect2, varscan2
- RBM18 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as COSV99938720; called by muse, mutect2, varscan2
- RELN | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100632032; called by muse, mutect2, varscan2
- RESF1 | c.3238A>G p.T1080A | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV100440004; called by muse, mutect2, varscan2
- RYR3 | c.5675T>C p.I1892T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV101211834; called by muse, mutect2, varscan2
- SCN4A | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as COSV101438287; called by muse, mutect2, varscan2
- SCRIB | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754579272, COSV100252319; called by muse, mutect2
- SI | c.4140C>A p.D1380E | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV100013546; called by muse, mutect2, varscan2
- SLC4A4 | c.2871G>T p.Q957H (on ENST00000264485 / NM_001098484.3; = p.Q913H on NM_003759.4) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99138817; called by muse, mutect2, varscan2
- SLCO3A1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs761312118, COSV100575536, COSV59234825; called by muse, mutect2, varscan2
- SNCAIP | c.964A>C p.I322L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.377); catalogued as COSV99746717; called by muse, mutect2
- SPINK4 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV101121870; called by muse, mutect2, varscan2
- SPINK5 | c.2836A>G p.T946A | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV99805982; called by muse, mutect2, varscan2
- SPTY2D1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100311457; called by muse, mutect2, varscan2
- SRSF1 | c.634C>A p.R212S | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99365184; called by muse, mutect2, varscan2
- STEAP2 | c.865A>T p.R289W | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99840174; called by muse, mutect2, varscan2
- TBCC | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.081); catalogued as COSV99773910; called by muse, mutect2, varscan2
- TDRD3 | c.1368G>C p.R456S | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99539624; called by muse, mutect2, varscan2
- TDRD5 | c.2252T>C p.M751T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.104); catalogued as COSV99675278; called by muse, mutect2, varscan2
- TFCP2 | c.1429A>G p.N477D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99227413; called by muse, mutect2, varscan2
- TMTC4 | c.288C>G p.Y96* (on ENST00000376234 / NM_001350577.2; = p.Y115* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/182 reads (4%) | catalogued as COSV100168398; called by muse, mutect2
- TNFSF10 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs11545817, COSV99577496; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs764635374, COSV100835741; called by muse, mutect2, varscan2
- TNR | c.1020G>C p.R340S | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV99686990; called by muse, mutect2, varscan2
- TOP2A | c.3944C>A p.T1315K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101352286; called by muse, mutect2, varscan2
- TP53 | c.709del p.M237Cfs*10 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as COSV52701833, COSV52875518, COSV53198341; called by mutect2, pindel, varscan2
- UNC79 | c.7745T>A p.I2582N (on ENST00000393151 / NM_001346218.2; = p.I2405N on NM_020818.5) | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99825330; called by muse, mutect2, varscan2
- USF3 | c.3395T>C p.I1132T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752517275, COSV100324633; called by muse, mutect2, varscan2
- UTS2R | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1367894512, COSV100493262; called by muse, mutect2
- WDR45 | c.842G>T p.G281V (on ENST00000376372 / NM_001029896.2; = p.G282V on NM_007075.3) | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100540064, COSV59876722; called by muse, mutect2, varscan2
- ZNF143 | c.347C>A p.T116K | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100217650; called by muse, mutect2, varscan2
- ZNF236 | c.5282A>G p.Q1761R | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV99468628; called by muse, mutect2, varscan2
- ZNF354B | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 140/325 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs747697057, COSV100482850; called by muse, mutect2, varscan2
- ZNF99 | c.1737T>A p.H579Q | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.051); catalogued as rs531461646, COSV101233642; called by muse, mutect2, varscan2
- ZSWIM8 | c.2021A>G p.Y674C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV101289760; called by muse, mutect2, varscan2
- ZYX | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as COSV100503492, COSV59558082; called by muse, mutect2, varscan2
- CPSF2 | c.1881_1912del p.L628Sfs*18 | Frame Shift Del (DEL) | VAF 55/235 reads (23%) | called by mutect2, pindel, varscan2
- ENKUR | c.428del p.P143Qfs*23 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ROBO4 | c.32_44delinsA p.G11_L15delinsE | In Frame Del (DEL) | VAF 72/243 reads (30%) | called by pindel, varscan2*
- TF | c.1276_1297+2del p.X426_splice | Splice Site (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- UGT1A6 | c.1466_1486del p.D489_L495del | In Frame Del (DEL) | VAF 12/139 reads (9%) | called by mutect2, pindel
- ADAM28 | c.768C>A p.I256= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99737471; called by muse, mutect2
- AK7 | c.2040G>A p.L680= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV50870117; called by muse, mutect2, varscan2
- ARID1A | c.1014G>A p.G338= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV100250042; called by muse, varscan2
- C16orf54 | c.279G>A p.E93= | Silent (SNP) | VAF 74/162 reads (46%) | catalogued as COSV100268385; called by muse, mutect2, varscan2
- CLEC14A | c.1443G>T p.A481= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV100643469; called by muse, mutect2, varscan2
- COLEC10 | c.276G>T p.G92= | Silent (SNP) | VAF 78/368 reads (21%) | catalogued as COSV100250470; called by muse, mutect2, varscan2
- CSMD2 | c.5550G>A p.L1850= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99584824; called by muse, mutect2, varscan2
- CSMD3 | c.2541G>T p.G847= (on ENST00000297405 / NM_001363185.1; = p.G743= on NM_052900.3) | Silent (SNP) | VAF 115/184 reads (63%) | catalogued as COSV99821898; called by muse, mutect2, varscan2
- CYP2C18 | c.921A>G p.R307= | Silent (SNP) | VAF 43/77 reads (56%) | catalogued as COSV99608156; called by muse, mutect2, varscan2
- EEF1E1 | c.300A>G p.S100= | Silent (SNP) | VAF 89/210 reads (42%) | catalogued as rs754252957, COSV101121229; called by muse, mutect2, varscan2
- ELMOD3 | c.702G>A p.A234= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs371072018; called by muse, mutect2, varscan2
- FAM204A | c.645A>G p.A215= | Silent (SNP) | VAF 69/145 reads (48%) | catalogued as rs781361703, COSV100977405; called by muse, mutect2, varscan2
- IRX1 | c.1437C>A p.S479= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as COSV100116171; called by muse, mutect2, varscan2
- KCNH7 | c.1689T>A p.A563= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as COSV100033638; called by muse, mutect2, varscan2
- LAMA1 | c.2298C>A p.G766= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as COSV101054652; called by muse, mutect2, varscan2
- MAP4 | c.1830G>T p.L610= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100805335; called by muse, mutect2, varscan2
- NFE2L3 | c.1056T>G p.P352= | Silent (SNP) | VAF 98/218 reads (45%) | catalogued as COSV99283415; called by muse, mutect2, varscan2
- OR11H6 | c.849G>A p.G283= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV59643778; called by muse, mutect2, varscan2
- PCARE | c.3177T>G p.P1059= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100527235; called by muse, mutect2
- PCDHB1 | c.1254T>C p.Y418= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV100127995; called by muse, mutect2, varscan2
- PDE11A | c.2313A>C p.S771= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs781486307, COSV99610575; called by muse, mutect2, varscan2
- PEX1 | c.1983G>C p.L661= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99951810, COSV99952269; called by muse, mutect2, varscan2
- PLA2G4C | c.684T>G p.P228= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100843807; called by muse, mutect2
- PPP1R3D | c.474T>C p.D158= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs747322374, COSV100674347; called by muse, mutect2, varscan2
- PXDC1 | c.27G>T p.T9= | Silent (SNP) | VAF 41/102 reads (40%) | catalogued as rs369797402, COSV100977343; called by muse, mutect2, varscan2
- RNF103 | c.198G>A p.K66= | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as COSV99409886; called by muse, mutect2, varscan2
- RYR2 | c.3639T>A p.G1213= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV100767284; called by muse, mutect2, varscan2
- SALL2 | c.945C>A p.A315= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100444062; called by muse, mutect2, varscan2
- SLC25A38 | c.519G>T p.G173= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV99827749; called by muse, mutect2, varscan2
- TAOK3 | c.2043G>T p.T681= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV101183377, COSV66826689; called by muse, mutect2, varscan2
- TDRD6 | c.258G>T p.V86= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV100286990; called by muse, mutect2, varscan2
- ZNF394 | c.513C>T p.R171= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV61794498; called by muse, mutect2, varscan2
- C3orf35 | n.1236G>T | RNA (SNP) | VAF 108/251 reads (43%) | called by muse, mutect2, varscan2
- DKC1 | c.1260-105A>T | Intron (SNP) | VAF 32/41 reads (78%) | catalogued as COSV101053815; called by muse, mutect2, varscan2
- DTWD2 | c.218+13650T>G | Intron (SNP) | VAF 252/638 reads (39%) | called by muse, varscan2
